CCDI case PBCKHM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/104eff52-ff3c-4dd6-84ce-7068a30227ce

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 2.8 years (1,020 days).

Biospecimens (3 samples)
- Sample 0DTUI5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DTUIF, 0DTUIU (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
